Somatic mutation profile of tumor specimen TCGA-BR-A4J5-01A (aliquot TCGA-BR-A4J5-01A-21D-A25D-08) from TCGA case TCGA-BR-A4J5, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 56.7 years (20,714 days).
Specimen TCGA-BR-A4J5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e1bfe52-67b7-4f54-85f6-8f372353528e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4J5-10A (Blood Derived Normal), aliquot TCGA-BR-A4J5-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb30d244-6643-4908-b581-114f11515324

The open-access MAF lists 87 somatic variants for this specimen: 65 protein-altering or splice-affecting, 17 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 17, Nonsense Mutation 4, RNA 3, 3'UTR 1, In Frame Del 1, Splice Region 1, Frame Shift Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 10/180 reads (6%) | catalogued as rs1553631860, CM150338, COSV62729563; ClinVar: pathogenic; called by muse, mutect2
- ADAM12 | c.1625A>C p.K542T | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100900748; called by muse, mutect2
- ARHGAP1 | c.461A>T p.N154I | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100357905; called by muse, mutect2, varscan2
- ARHGAP5 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565487; called by muse, mutect2, varscan2
- ARID1A | c.1504C>T p.Q502* | Nonsense Mutation (SNP) | VAF 53/380 reads (14%) | catalogued as COSV100252204; called by muse, mutect2, varscan2
- BASP1 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs1246872010, COSV100493772; called by muse, mutect2, varscan2
- BRINP3 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1247221610, COSV66513875; called by muse, mutect2
- CHD4 | c.2590C>T p.R864W (on ENST00000357008 / NM_001363606.2; = p.R877W on NM_001273.5) | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58898273; called by muse, mutect2
- CHST10 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99959069; called by muse, mutect2, varscan2
- CNTN3 | c.1523A>C p.N508T | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as COSV99724976; called by muse, mutect2
- CPEB1 | c.1567G>T p.D523Y (on ENST00000617958; = p.D458Y on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55621554, COSV99917797; called by muse, mutect2, varscan2
- CUBN | c.9086A>C p.K3029T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV64709947, COSV64724848; called by muse, mutect2, varscan2
- DDX39B | c.339G>A p.Q113= | Splice Region (SNP) | VAF 13/216 reads (6%) | catalogued as COSV100795234; called by muse, mutect2
- DIRAS2 | c.188C>T p.T63M | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775534494, COSV65370426; called by muse, mutect2, varscan2
- FGD1 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs746549256, COSV100911078; called by muse, mutect2, varscan2
- FLG2 | c.2290A>G p.R764G | Missense Mutation (SNP) | VAF 50/554 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV101165964; called by muse, mutect2
- FMR1 | c.676A>T p.R226* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | catalogued as COSV99503426; called by muse, mutect2, varscan2
- FOXD3 | c.754A>G p.M252V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as COSV64379876, COSV64380210; called by muse, mutect2, varscan2
- FRG2 | c.591G>T p.Q197H | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as COSV66460287; called by muse, mutect2
- GNE | c.1840A>G p.S614G (on ENST00000396594 / NM_001128227.3; = p.S583G on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as COSV100930015; called by muse, mutect2, varscan2
- HDAC7 | c.1993C>T p.R665W (on ENST00000427332; = p.R704W on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50345329; called by muse, mutect2
- HECTD2 | c.2111A>T p.K704M | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99978703; called by muse, mutect2
- HOXA7 | c.257A>G p.D86G | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1450272157, COSV99636554; called by muse, mutect2
- INTS10 | c.1893G>C p.M631I | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.922); catalogued as COSV101208707; called by muse, mutect2, varscan2
- ITPR1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100231880; called by muse, mutect2
- KCNC2 | c.946A>C p.N316H | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100129145; called by muse, mutect2, varscan2
- KCNU1 | c.3199G>A p.E1067K | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV67754303; called by muse, mutect2
- LHCGR | c.1804A>C p.T602P | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99683851; called by muse, mutect2
- LRP1B | c.9280G>T p.V3094F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101257936, COSV67206765; called by muse, mutect2, varscan2
- LRRIQ4 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as rs1168352687, COSV100540286, COSV61620061; called by muse, mutect2
- LRRTM1 | c.1181T>C p.L394P | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV99702754; called by muse, mutect2
- MBD5 | c.3895C>T p.R1299W | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs370659853; called by muse, mutect2, varscan2
- MC3R | c.293T>A p.I98N | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99710673; called by muse, mutect2, varscan2
- MPDZ | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as rs577701969, COSV100062741; called by muse, mutect2, varscan2
- MTA3 | c.1335G>C p.Q445H | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100780935; called by muse, mutect2
- NSF | c.2213+1G>A p.X738_splice | Splice Site (SNP) | VAF 7/44 reads (16%) | catalogued as rs747961356, COSV99833900; called by muse, mutect2, varscan2
- OBP2B | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs782276020, COSV100922879; called by muse, mutect2
- OGDHL | c.2881A>G p.T961A | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV65104520; called by muse, mutect2, varscan2
- OPRL1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs937030973, COSV100402136; called by muse, mutect2, varscan2
- PCDH11Y | c.551C>T p.S184L (on ENST00000400457 / NM_032973.2; = p.S173L on NM_032971.3) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as COSV99291846; called by mutect2, varscan2
- PCDHB5 | c.551A>C p.N184T | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.084); catalogued as COSV99168678; called by muse, mutect2, varscan2
- PCDHB5 | c.2218G>C p.G740R | Missense Mutation (SNP) | VAF 24/291 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.202); catalogued as COSV99168713; called by muse, mutect2
- PLD5 | c.825C>A p.F275L (on ENST00000442594; = p.F213L on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100141681, COSV59146928; called by muse, mutect2, varscan2
- PLEKHG1 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1243766874, COSV62046970; called by muse, mutect2, varscan2
- PLXNA4 | c.2879A>C p.K960T | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100325123; called by muse, mutect2
- PRICKLE2 | c.2350C>T p.R784C (on ENST00000295902; = p.R728C on NM_198859.4) | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.498); catalogued as rs780553569; called by muse, mutect2
- PROKR1 | c.347G>T p.C116F | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV100375593; called by muse, mutect2, varscan2
- PZP | c.3428A>G p.E1143G | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV99736400; called by muse, mutect2, varscan2
- RNF180 | c.683C>A p.S228* | Nonsense Mutation (SNP) | VAF 8/96 reads (8%) | catalogued as COSV56961833; called by muse, mutect2
- SCRIB | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs767960644, COSV57590429; called by muse, mutect2, varscan2
- SDHC | c.450G>T p.Q150H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100713705; called by muse, varscan2
- SEPTIN4 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs779838958, COSV57898552; called by muse, varscan2
- SPDL1 | c.548_550del p.E183del | In Frame Del (DEL) | VAF 6/44 reads (14%) | catalogued as rs1462822633; called by pindel, varscan2
- SYCP2L | c.1338G>T p.M446I | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99305391; called by muse, mutect2
- TNRC6A | c.4730T>C p.M1577T | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV100170175; called by muse, varscan2
- TRPS1 | c.1394G>C p.G465A (on ENST00000220888 / NM_001330599.2; = p.G478A on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99631957; called by muse, mutect2
- TTN | c.2771C>A p.A924D (on ENST00000591111; = p.A878D on NM_003319.4) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | PolyPhen benign (0.203); catalogued as COSV100618621; called by muse, mutect2
- WIF1 | c.524A>T p.K175I | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99683037; called by muse, mutect2, varscan2
- ZBTB38 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs1358441969, COSV100375752; called by muse, mutect2
- ZFP42 | c.98G>T p.S33I | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV58819020, COSV58819428; called by muse, mutect2, varscan2
- ZNF208 | c.2508A>C p.K836N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.709); catalogued as COSV68105115; called by muse, mutect2, varscan2
- ZNF570 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1316250674, COSV100356227; called by muse, mutect2
- ZNF831 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs143620250, COSV100926147; called by muse, mutect2, varscan2
- ARHGEF10 | c.3614_3618del p.Y1205Cfs*55 (on ENST00000398564; = p.Y1180Cfs*55 on NM_014629.4) | Frame Shift Del (DEL) | VAF 7/74 reads (9%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.492A>T p.E164D | Missense Mutation (SNP) | VAF 34/531 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.521); called by muse, mutect2
- ANGPTL2 | c.969G>A p.L323= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as COSV99401905; called by muse, mutect2, varscan2
- BAIAP3 | c.3267C>T p.A1089= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs778962626, COSV50104419; called by muse, mutect2, varscan2
- CDH6 | c.1638G>A p.T546= | Silent (SNP) | VAF 11/117 reads (9%) | catalogued as COSV54077357; called by muse, mutect2
- EPHB2 | c.2556G>T p.P852= (on ENST00000400191 / NM_001309193.2; = p.P853= on NM_004442.7) | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV101007173; called by muse, mutect2, varscan2
- FASLG | c.840G>A p.K280= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs749748178, COSV60680206; called by muse, mutect2, varscan2
- FCRL1 | c.954T>G p.G318= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV100839828; called by muse, mutect2, varscan2
- GGN | c.393C>T p.R131= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99287529; called by muse, mutect2
- GRB14 | c.630T>G p.S210= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99814167; called by muse, mutect2, varscan2
- GRM3 | c.1303T>C p.L435= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as COSV64471679, COSV64480196; called by muse, mutect2
- LMLN | c.1131C>T p.N377= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100218684; called by muse, mutect2, varscan2
- LRP2 | c.12111G>A p.T4037= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as rs745582154, COSV55558718, COSV99788683; called by muse, mutect2
- MS4A10 | c.657G>A p.P219= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as rs778879291, COSV100382339; called by muse, mutect2, varscan2
- PCDH10 | c.2883T>C p.S961= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV99993878; called by muse, mutect2, varscan2
- PKLR | c.789G>C p.G263= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV100712946; called by muse, mutect2
- PRKCB | c.1449C>T p.A483= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as rs746954626, COSV100334470; called by muse, mutect2, varscan2
- SFMBT1 | c.2157C>T p.S719= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as rs138166180; called by muse, mutect2, varscan2
- ZNF2 | c.1215G>A p.T405= (on ENST00000611147 / NM_001291605.2; = p.T392= on NM_021088.4) | Silent (SNP) | VAF 8/135 reads (6%) | catalogued as rs575836528; called by muse, mutect2
- BIRC8 | n.1201A>C | RNA (SNP) | VAF 10/88 reads (11%) | catalogued as COSV101461332; called by muse, mutect2, varscan2
- MIR376A2 | n.73T>C | RNA (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- RGS6 | c.1368+3808A>G | Intron (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100666470; called by muse, mutect2
- SLC30A10 | c.*2C>A | 3'UTR (SNP) | VAF 64/246 reads (26%) | catalogued as COSV100751534; called by muse, mutect2, varscan2
- SNORD114-14 | n.23G>A | RNA (SNP) | VAF 5/52 reads (10%) | catalogued as rs369654331; called by muse, mutect2, varscan2
